Somatic mutation profile of tumor specimen TCGA-22-4593-01A (aliquot TCGA-22-4593-01A-21D-1817-08) from TCGA case TCGA-22-4593, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.7 years (28,385 days).
Specimen TCGA-22-4593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1942f1c-439e-4b9b-8ffd-7a5241117233.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4593-11A (Solid Tissue Normal), aliquot TCGA-22-4593-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c8e1198-accb-4689-b541-62c83fb22528

The open-access MAF lists 200 somatic variants for this specimen: 149 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 48, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 4, In Frame Del 2, RNA 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 27/37 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.221A>C p.N74T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52025640; called by muse, mutect2
- ACOT12 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs377749793; called by muse, mutect2, varscan2
- ADAMTS10 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1555739413, CM142271, COSV54352645, COSV99547162; called by muse, mutect2, varscan2
- AGO1 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV64596210; called by muse, mutect2, varscan2
- AKAP13 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63466294; called by muse, mutect2, varscan2
- AKAP6 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs150211003; called by muse, mutect2, varscan2
- ALG13 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 151/325 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs771783840, COSV52643634; called by muse, mutect2, varscan2
- ANKS1B | c.2224C>T p.L742F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61368383; called by muse, mutect2, varscan2
- ANTXR2 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV56318552; called by muse, mutect2, varscan2
- AP002512.3 | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV54408275; called by muse, mutect2, varscan2
- ASB16 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53234918, COSV53236044; called by muse, mutect2
- BCAS1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.523); catalogued as COSV65088574; called by muse, mutect2, varscan2
- BPIFB4 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64950766; called by muse, mutect2, varscan2
- C16orf78 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV54557895; called by muse, mutect2, varscan2
- C5AR2 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99953731; called by muse, mutect2, varscan2
- CANT1 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1439551268, COSV56606466; called by muse, mutect2, varscan2
- CDK16 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1422835444, COSV52092956; called by muse, mutect2, varscan2
- CETN1 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59122001; called by muse, mutect2, varscan2
- COL19A1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 59/146 reads (40%) | catalogued as COSV59583450; called by muse, mutect2, varscan2
- CR2 | c.1652C>T p.T551M | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs778084554, COSV65505999, COSV65506074; called by muse, mutect2, varscan2
- CRHR1 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as rs911300898, COSV53284105; called by muse, mutect2, varscan2
- CUL9 | c.4556G>C p.R1519P | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52732827; called by muse, mutect2, varscan2
- CXCR4 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54010912, COSV54015485; called by muse, mutect2, varscan2
- DBNDD1 | c.297C>G p.N99K (on ENST00000002501 / NM_001042610.3; = p.N119K on NM_024043.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV50022536; called by muse, mutect2, varscan2
- DCAF12 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 119/162 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.243); catalogued as COSV63513433; called by muse, mutect2, varscan2
- DCDC1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV60854425; called by muse, mutect2, varscan2
- DDX42 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.005); catalogued as rs768506423, COSV63790985; called by muse, mutect2, varscan2
- DLL1 | c.1768A>T p.M590L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV64538326; called by muse, mutect2, varscan2
- DUSP22 | c.120T>G p.S40R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60530002; called by muse, mutect2, varscan2
- EFCAB5 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57935019; called by muse, mutect2, varscan2
- EFR3A | c.1584A>T p.Q528H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV54461153; called by muse, mutect2, varscan2
- ENPP7 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs782664704, COSV60387552; called by muse, mutect2, varscan2
- EPHA5 | c.1987G>T p.V663F | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56665713; called by muse, mutect2, varscan2
- EYS | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs867129390, COSV60996902, COSV60998534; called by muse, mutect2, varscan2
- FBN3 | c.4346G>C p.C1449S | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54469325; called by muse, mutect2, varscan2
- FCHO2 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); catalogued as COSV59275558, COSV59276164; called by muse, mutect2, varscan2
- FETUB | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs541290079, COSV54006855; called by muse, mutect2, varscan2
- FMO1 | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61447309; called by muse, mutect2, varscan2
- FN1 | c.3775A>G p.I1259V | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60560804; called by muse, mutect2, varscan2
- FYTTD1 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV54085468; called by muse, mutect2, varscan2
- GALNT13 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV67224873; called by muse, mutect2, varscan2
- GNL2 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as COSV56169248, COSV56171120; called by muse, mutect2, varscan2
- GRIN1 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59299659; called by muse, mutect2, varscan2
- GRIP1 | c.1294A>T p.T432S (on ENST00000359742 / NM_001379345.1; = p.T380S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV54037070; called by muse, mutect2, varscan2
- GUCY1A1 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56655075; called by muse, mutect2, varscan2
- HCN1 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 41/154 reads (27%) | catalogued as COSV57506828, COSV57514204; called by muse, mutect2, varscan2
- HELZ2 | c.3269G>A p.G1090E (on ENST00000467148 / NM_001037335.2; = p.G521E on NM_033405.3) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV64410309; called by muse, mutect2, varscan2
- HERC2 | c.14398G>A p.A4800T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55322413; called by muse, mutect2, varscan2
- IFT74 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66288276; called by muse, mutect2, varscan2
- ILF3 | c.960C>T p.H320= | Splice Region (SNP) | VAF 19/98 reads (19%) | catalogued as rs1568231431, COSV51559458; called by muse, mutect2, varscan2
- INSR | c.3220G>T p.E1074* | Nonsense Mutation (SNP) | VAF 39/91 reads (43%) | catalogued as CM1312626, COSV57170530; called by muse, mutect2, varscan2
- ITIH6 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); catalogued as COSV54493075; called by muse, mutect2, varscan2
- KCNH3 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57790414; called by muse, mutect2, varscan2
- KCNH7 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59786202; called by muse, mutect2, varscan2
- KHDC4 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV64165514; called by muse, mutect2, varscan2
- KIZ | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as COSV55687399; called by muse, mutect2
- KLB | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs769625563, COSV57304031; called by muse, mutect2, varscan2
- KRIT1 | c.1490T>A p.L497Q | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60669914; called by muse, mutect2, varscan2
- LDHD | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55580205, COSV55581731; called by muse, mutect2, varscan2
- LMTK2 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52001734; called by muse, mutect2, varscan2
- LRP1 | c.4162C>T p.H1388Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV54521347; called by muse, mutect2, varscan2
- LRP12 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs186127441, COSV52626685, COSV52632925; called by muse, mutect2, varscan2
- LRP1B | c.10111C>A p.L3371I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.793); catalogued as COSV67260217; called by muse, mutect2, varscan2
- LRP1B | c.8855A>G p.K2952R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV67260218; called by muse, mutect2, varscan2
- LRP1B | c.7274G>A p.R2425K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs201905999, COSV67260219; called by muse, mutect2, varscan2
- LRRC37A3 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100141009; called by muse, varscan2
- MACF1 | c.4913C>T p.S1638F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV57137444; called by muse, mutect2, varscan2
- MAGI1 | c.4315G>T p.G1439C | Missense Mutation (SNP) | VAF 163/218 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV58339176; called by muse, mutect2, varscan2
- MAP3K21 | c.1394A>T p.Q465L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV64045997; called by muse, mutect2, varscan2
- MEAK7 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59145171; called by muse, mutect2, varscan2
- MELTF | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372423742; called by muse, mutect2, varscan2
- MFSD5 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61566046; called by muse, mutect2, varscan2
- MIA3 | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV60516430; called by muse, mutect2, varscan2
- MINAR1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV59585597; called by muse, mutect2, varscan2
- MLLT10 | c.2375C>T p.S792F (on ENST00000307729 / NM_001195626.3; = p.S808F on NM_004641.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs1383606493, COSV57001952, COSV57002130; called by muse, mutect2, varscan2
- MMP16 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV54182863, COSV54192050; called by muse, mutect2, varscan2
- MRC2 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57643256; called by muse, mutect2, varscan2
- MS4A15 | c.498+2T>C p.X166_splice (on ENST00000405633 / NM_001098835.2; = p.X73_splice on NM_152717.3) | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as COSV61961699; called by muse, mutect2, varscan2
- MYH15 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs768209260, COSV56317111; called by muse, mutect2, varscan2
- MYOCD | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58509583; called by muse, varscan2
- MYOM2 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV50753601; called by muse, mutect2, varscan2
- NHS | c.4100C>T p.A1367V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV66280458; called by muse, mutect2, varscan2
- NOTCH4 | c.5912G>T p.C1971F | Missense Mutation (SNP) | VAF 90/122 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV66682999; called by muse, mutect2, varscan2
- NT5E | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV57629822; called by muse, mutect2, varscan2
- OR1M1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs372082145, COSV70037394; called by muse, mutect2, varscan2
- OR4M1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV60063001; called by muse, mutect2, varscan2
- OR5B12 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV56906248; called by muse, mutect2, varscan2
- OSTN | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59140623; called by muse, mutect2, varscan2
- OXR1 | c.898C>T p.H300Y (on ENST00000442977 / NM_001198532.1; = p.H299Y on NM_018002.3) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs757421094, COSV56334357; called by muse, mutect2, varscan2
- PDE4DIP | c.5006C>A p.A1669D | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV57720318, COSV57727968; called by muse, mutect2, varscan2
- PEAK1 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 82/270 reads (30%) | catalogued as COSV56941192; called by muse, mutect2, varscan2
- PEX14 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs553512429, COSV63059856, COSV63060714; called by muse, mutect2, varscan2
- PFKM | c.1413-1G>C p.X471_splice | Splice Site (SNP) | VAF 35/218 reads (16%) | catalogued as COSV56659631; called by muse, mutect2, varscan2
- PFKM | c.1413G>C p.R471S | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56659643; called by muse, mutect2, varscan2
- PIK3C2G | c.3453C>G p.S1151R (on ENST00000676171; = p.S1110R on NM_004570.5) | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56826691; called by muse, mutect2, varscan2
- PKD1L1 | c.5153+1G>T p.X1718_splice | Splice Site (SNP) | VAF 15/92 reads (16%) | catalogued as rs1353107051, COSV99219412; called by muse, mutect2, varscan2
- PKD1L1 | c.5153G>T p.S1718I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56974606; called by muse, mutect2, varscan2
- PLCXD3 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs752338054, COSV60615193; called by muse, mutect2, varscan2
- PLEKHH2 | c.3197A>C p.H1066P | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56759128; called by muse, mutect2, varscan2
- PLOD2 | c.351A>G p.I117M | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV51467752; called by muse, mutect2, varscan2
- PRB3 | c.787C>G p.P263A (on ENST00000381842; = p.P305A on NM_006249.5) | Missense Mutation (SNP) | VAF 195/373 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV54392520; called by muse, mutect2, varscan2
- QRFPR | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV57679404; called by muse, mutect2, varscan2
- RALGPS2 | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV61339172; called by muse, mutect2, varscan2
- RASIP1 | c.2566A>T p.T856S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV55807367; called by muse, mutect2, varscan2
- RIMS2 | c.4573G>T p.G1525* (on ENST00000666250 / NM_001348490.2; = p.G1096* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/188 reads (19%) | catalogued as COSV51712201, COSV99164651; called by muse, mutect2, varscan2
- RMDN3 | c.1198del p.E400Kfs*8 | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | catalogued as COSV99540255; called by mutect2, pindel, varscan2
- RNF168 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV58839127; called by muse, mutect2, varscan2
- RNF17 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55048037; called by muse, mutect2, varscan2
- RORC | c.557A>T p.Y186F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV59094891; called by muse, mutect2, varscan2
- RPS6KA5 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56224376; called by muse, mutect2, varscan2
- RUNX2 | c.1325C>G p.T442S (on ENST00000371438; = p.T420S on NM_001015051.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.401); catalogued as COSV61844686; called by muse, mutect2, varscan2
- SATB2 | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99611132; called by muse, mutect2, varscan2
- SIDT1 | c.1857+2T>C p.X619_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | catalogued as COSV53505586; called by muse, mutect2, varscan2
- SLC25A38 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as COSV56195170; called by muse, mutect2, varscan2
- SLC2A7 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1373827023, COSV68902247; called by muse, mutect2, varscan2
- SLC5A11 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61743161; called by muse, mutect2, varscan2
- SLC6A3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs761418909, COSV54368242; called by muse, mutect2, varscan2
- SLFN11 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as COSV57700096; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 81/139 reads (58%) | PolyPhen benign (0.017); catalogued as COSV50078610; called by muse, mutect2, varscan2
- STAB2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as rs201489210, COSV66335978; called by muse, mutect2, varscan2
- STON1 | c.1207G>T p.V403F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59135889; called by muse, mutect2, varscan2
- TARBP1 | c.4169C>T p.A1390V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs527984546, COSV50196297; called by muse, mutect2, varscan2
- TBPL2 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.129); catalogued as rs777230784, COSV55972438; called by muse, mutect2, varscan2
- TBXAS1 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54951781; called by muse, mutect2, varscan2
- TMCO1 | c.395G>T p.R132I (on ENST00000612311 / NM_001256164.1; = p.R81I on NM_019026.6) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63318894; called by muse, varscan2
- TNFAIP2 | c.1425A>C p.P475= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as COSV60695711; called by muse, mutect2, varscan2
- TNFRSF8 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55799579; called by muse, mutect2, varscan2
- TRIO | c.1804C>G p.R602G | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60091843, COSV60101515; called by muse, mutect2, varscan2
- WARS1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs146689917, COSV100690118, COSV59925963; called by muse, mutect2, varscan2
- WNK4 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV55908821; called by muse, mutect2, varscan2
- YAE1 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs749934423, COSV56233531; called by muse, mutect2, varscan2
- ZFYVE1 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433679547, COSV59612455; called by muse, mutect2, varscan2
- ZKSCAN3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV52853937; called by muse, mutect2, varscan2
- ZNF492 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV71762287; called by muse, mutect2, varscan2
- ZNF492 | c.1462A>T p.N488Y | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (1); PolyPhen possibly damaging (0.861); catalogued as COSV71762288; called by muse, mutect2, varscan2
- ZNF534 | c.674A>C p.K225T (on ENST00000332323 / NM_001143939.3; = p.K212T on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV56520156; called by muse, mutect2, varscan2
- ZNF808 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV63121145; called by muse, mutect2, varscan2
- ZNF99 | c.2413A>G p.R805G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV68056375; called by muse, mutect2, varscan2
- ADCY2 | c.1491_1494del p.Y497* | Frame Shift Del (DEL) | VAF 40/79 reads (51%) | called by mutect2, pindel, varscan2
- FBXW7 | c.2001dup p.S668Efs*26 (on ENST00000281708 / NM_001349798.2; = p.S588Efs*26 on NM_018315.5) | Frame Shift Ins (INS) | VAF 105/291 reads (36%) | called by mutect2, pindel, varscan2
- IGHA1 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, varscan2
- IGHA2 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by mutect2, varscan2
- IGHE | c.1182G>T p.R394S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC15A1 | c.586del p.A196Lfs*16 | Frame Shift Del (DEL) | VAF 55/107 reads (51%) | called by mutect2, pindel, varscan2
- TGFBRAP1 | c.1495_1506del p.N499_D502del | In Frame Del (DEL) | VAF 60/251 reads (24%) | called by mutect2, pindel, varscan2
- TMEM63A | c.1144del p.Q382Sfs*55 | Frame Shift Del (DEL) | VAF 101/247 reads (41%) | called by mutect2, pindel, varscan2
- TP53 | c.145_160del p.D49Sfs*69 | Frame Shift Del (DEL) | VAF 100/177 reads (56%) | called by mutect2, pindel, varscan2
- TRAF3IP1 | c.453_455del p.N151del | In Frame Del (DEL) | VAF 28/65 reads (43%) | called by pindel, varscan2
- ADIPOR1 | c.924G>T p.V308= | Silent (SNP) | VAF 37/165 reads (22%) | catalogued as COSV61850946, COSV61851939; called by muse, mutect2, varscan2
- ARL6IP6 | c.30G>A p.S10= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV58443840; called by muse, mutect2, varscan2
- C3orf38 | c.666G>A p.L222= | Silent (SNP) | VAF 28/278 reads (10%) | catalogued as COSV59628800; called by muse, mutect2, varscan2
- COG6 | c.852G>A p.A284= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs767076532, COSV62997093; called by muse, mutect2, varscan2
- COPB1 | c.1239C>T p.N413= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs149921106, COSV51450186; called by muse, mutect2, varscan2
- COPS3 | c.951A>G p.L317= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs141030201, COSV52006893; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1362G>A p.G454= | Silent (SNP) | VAF 75/198 reads (38%) | catalogued as rs767664409, COSV54746252; called by muse, mutect2, varscan2
- DAPK3 | c.900G>A p.T300= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs1354633913, COSV56664298; called by muse, mutect2, varscan2
- DLGAP1 | c.228C>A p.T76= | Silent (SNP) | VAF 67/122 reads (55%) | catalogued as COSV59826785; called by muse, mutect2, varscan2
- DSCAM | c.918C>T p.G306= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as rs1476813011, COSV68033340; called by muse, mutect2, varscan2
- EPHA5 | c.3048G>A p.Q1016= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV56633729; called by muse, mutect2, varscan2
- FAT4 | c.13464G>T p.G4488= | Silent (SNP) | VAF 70/153 reads (46%) | catalogued as COSV100628440, COSV100628638, COSV58702315; called by muse, mutect2, varscan2
- FBXL18 | c.1419C>T p.S473= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs560947191, COSV66107810; called by muse, mutect2, varscan2
- FBXW10 | c.2814T>C p.S938= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100111387; called by muse, mutect2, varscan2
- FCGR1A | c.1113G>A p.Q371= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1553751919, COSV64985924; called by muse, mutect2, varscan2
- GNPTAB | c.2943A>G p.S981= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV68449898; called by muse, mutect2, varscan2
- GPRC5B | c.831G>C p.A277= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs773501710, COSV56028190; called by muse, mutect2, varscan2
- HMGCS2 | c.618T>C p.R206= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV65568943; called by muse, mutect2, varscan2
- HS3ST5 | c.447G>A p.Q149= | Silent (SNP) | VAF 100/198 reads (51%) | catalogued as COSV57148591; called by muse, mutect2, varscan2
- IGSF9 | c.1359C>G p.T453= (on ENST00000368094 / NM_001135050.2; = p.T437= on NM_020789.4) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV63641685; called by muse, mutect2, varscan2
- INTS1 | c.291G>A p.V97= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as COSV67179174; called by muse, mutect2, varscan2
- INTS14 | c.951A>G p.L317= (on ENST00000313182 / NM_001366360.2; = p.L238= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as COSV57527554; called by muse, mutect2, varscan2
- KIF17 | c.975G>A p.T325= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs778098436, COSV56121453; called by muse, mutect2, varscan2
- LAMC2 | c.2334G>A p.L778= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs760487987, COSV51458723; called by muse, mutect2, varscan2
- MAP3K1 | c.2928C>T p.S976= | Silent (SNP) | VAF 7/150 reads (5%) | catalogued as COSV68126277; called by muse, mutect2
- MIA3 | c.5244G>A p.R1748= | Silent (SNP) | VAF 80/311 reads (26%) | catalogued as COSV60516438; called by muse, mutect2, varscan2
- MROH1 | c.4473G>A p.Q1491= | Silent (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- NCKAP1L | c.612C>T p.A204= | Silent (SNP) | VAF 113/378 reads (30%) | catalogued as COSV53210867; called by muse, mutect2, varscan2
- NDST3 | c.138G>A p.T46= | Silent (SNP) | VAF 113/297 reads (38%) | catalogued as rs145505386; called by muse, mutect2, varscan2
- NTN3 | c.996C>T p.R332= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV53548085; called by muse, mutect2, varscan2
- OR2W3 | c.294C>T p.A98= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV64457769; called by muse, mutect2, varscan2
- PC | c.1545G>T p.P515= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV58921225, COSV58922551; called by muse, mutect2, varscan2
- PDE6C | c.2511C>T p.A837= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs769552362, COSV63273362; called by muse, mutect2, varscan2
- RAB5B | c.396G>A p.G132= | Silent (SNP) | VAF 42/171 reads (25%) | catalogued as COSV64365150; called by muse, mutect2, varscan2
- RYR1 | c.13950G>A p.L4650= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV62092872, COSV62106931; called by muse, mutect2, varscan2
- SALL3 | c.1476C>T p.P492= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV73306365; called by muse, mutect2, varscan2
- SEZ6L2 | c.1515C>A p.A505= (on ENST00000308713 / NM_001114099.3; = p.A435= on NM_012410.4) | Silent (SNP) | VAF 143/291 reads (49%) | catalogued as COSV58102278; called by muse, mutect2, varscan2
- SIGLEC9 | c.147C>A p.G49= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV51587040; called by muse, mutect2, varscan2
- SLC6A14 | c.630G>T p.G210= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV64148196; called by muse, mutect2, varscan2
- SOGA1 | c.1263G>A p.S421= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as rs760371608, COSV52927543; called by muse, mutect2, varscan2
- TAF1C | c.1185G>T p.A395= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV58988297; called by muse, mutect2, varscan2
- TLR4 | c.1347C>T p.L449= (on ENST00000355622 / NM_138554.5; = p.L409= on NM_003266.4) | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs1213497608, COSV62923997; called by muse, mutect2, varscan2
- TRIM21 | c.819C>T p.C273= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54345769; called by muse, mutect2, varscan2
- UBXN4 | c.591C>T p.I197= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1254590757, COSV55637125; called by muse, mutect2, varscan2
- USH2A | c.7815A>G p.S2605= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as rs1558146521, COSV56416874; called by muse, mutect2, varscan2
- WDFY1 | c.27G>A p.P9= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51791831; called by muse, mutect2, varscan2
- XYLT1 | c.2869C>A p.R957= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV54493472; called by muse, mutect2, varscan2
- ZNFX1 | c.2169G>A p.K723= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV65578153; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503835 G>A | 5'Flank (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- C6orf223 | n.697G>T | RNA (SNP) | VAF 73/99 reads (74%) | catalogued as COSV60735953; called by muse, mutect2, varscan2
- LINC01098 | n.511T>C | RNA (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
